Somatic mutation profile of tumor specimen TCGA-MA-AA3X-01A (aliquot TCGA-MA-AA3X-01A-22D-A42O-09) from TCGA case TCGA-MA-AA3X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 50.4 years (18,412 days).
Specimen TCGA-MA-AA3X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efe5f2b3-5655-47db-90ac-f57feb07b9b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA3X-10A (Blood Derived Normal), aliquot TCGA-MA-AA3X-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00d98b84-4417-4c1f-b75e-ec4d788c0a78

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 23, Nonsense Mutation 3, Frame Shift Del 2, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/172 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV101024026; called by muse, mutect2, varscan2
- AMOTL2 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs766621996, COSV99850570; called by muse, mutect2, varscan2
- ANGPT1 | c.1284A>C p.K428N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99861833; called by muse, mutect2
- ARHGDIB | c.342+1G>T p.X114_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99967242; called by muse, mutect2, varscan2
- BPIFB4 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100971405; called by muse, mutect2, varscan2
- BUB1B | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV99806516; called by muse, mutect2, varscan2
- CACNA1A | c.4217T>A p.F1406Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM014169, COSV100800688; called by muse, mutect2, varscan2
- COL13A1 | c.862G>C p.G288R (on ENST00000398978 / NM_001130103.2; = p.G231R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637249; called by muse, mutect2, varscan2
- COL4A4 | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100306116; called by muse, mutect2, varscan2
- CRY1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs149558160; called by muse, mutect2, varscan2
- DICER1 | c.2118C>T p.G706= | Splice Region (SNP) | VAF 37/59 reads (63%) | catalogued as rs191755360, COSV100601729; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DIPK1A | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV100941929; called by muse, mutect2, varscan2
- EHMT2 | c.3116G>A p.R1039Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99998562; called by muse, mutect2, varscan2
- ELL3 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100082449; called by muse, mutect2, varscan2
- ERICH3 | c.2595A>C p.K865N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100443306; called by muse, mutect2, varscan2
- FMNL1 | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV58958290; called by muse, mutect2, varscan2
- FOXO3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100669514, COSV59629297; called by muse, mutect2, varscan2
- GPR52 | c.674A>T p.H225L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as COSV99267329; called by muse, mutect2, varscan2
- HSPA12B | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99421925; called by muse, varscan2
- KCNH1 | c.2077C>T p.R693W (on ENST00000271751 / NM_172362.3; = p.R666W on NM_002238.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764518229, COSV99656969, COSV99658905; called by muse, mutect2, varscan2
- KLHDC4 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV99565966; called by muse, mutect2, varscan2
- KLHL14 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs749190889, COSV100808596, COSV63832501; called by muse, mutect2, varscan2
- LIFR | c.2095T>A p.F699I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV99663158; called by muse, mutect2, varscan2
- MAGEB16 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV101303271; called by mutect2, varscan2
- MAP3K1 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV68122561; called by muse, mutect2, varscan2
- MYD88 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100085750; called by muse, mutect2, varscan2
- MYH8 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV101238131; called by muse, mutect2, varscan2
- NSD1 | c.5377G>A p.E1793K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV61787922; called by muse, mutect2, varscan2
- OR10H2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs751844869, COSV59945682; called by muse, mutect2, varscan2
- OR2AK2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100823071; called by mutect2, varscan2
- OSR2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52558102; called by mutect2, varscan2
- PARP14 | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs922423588, COSV101506220; called by muse, mutect2, varscan2
- PMPCA | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100047992; called by muse, mutect2, varscan2
- RET | c.2277G>A p.M759I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100392179, COSV60698966; called by muse, mutect2, varscan2
- REV3L | c.7415A>C p.N2472T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.029); catalogued as COSV100724825; called by muse, mutect2, varscan2
- RNF31 | c.2528A>G p.D843G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100141508; called by muse, mutect2, varscan2
- SELENOO | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as rs201408834, COSV66600994; called by muse, mutect2, varscan2
- SERPINA5 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100291432, COSV61573731; called by muse, mutect2
- SHE | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1451472582, COSV59071639; called by muse, mutect2, varscan2
- SIPA1L3 | c.4338C>G p.F1446L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV99727184; called by muse, mutect2
- SPEF2 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs774221694, COSV56797280; called by muse, mutect2, varscan2
- UGT2A3 | c.1502C>G p.T501S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV99279561; called by muse, mutect2
- USP33 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756513586, COSV62468434; called by muse, mutect2
- WDR17 | c.369C>A p.D123E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV99706657; called by muse, mutect2, varscan2
- ZNF519 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV73913302; called by muse, mutect2, varscan2
- ZNF608 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100100889; called by muse, mutect2, varscan2
- ZSWIM2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs573856511, COSV54578099; called by muse, mutect2, varscan2
- CIC | c.3205_3208del p.Q1069Wfs*23 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel
- GPR107 | c.1631del p.Y544Lfs*27 (on ENST00000372406 / NM_001136557.2; = p.Y496Lfs*27 on NM_020960.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- MRC1 | c.3376C>T p.H1126Y | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.4569T>C p.T1523= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101329912; called by muse, mutect2, varscan2
- BCAN | c.117C>T p.I39= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61255608; called by muse, mutect2, varscan2
- CATSPER2 | c.1146A>C p.A382= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100390524; called by muse, mutect2, varscan2
- CES4A | c.615C>T p.I205= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1302025787, COSV58654388; called by muse, mutect2, varscan2
- ELK4 | c.1176A>G p.Q392= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs771878445, COSV99222239; called by muse, mutect2, varscan2
- FILIP1 | c.3591G>A p.L1197= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99383771; called by muse, mutect2, varscan2
- FMNL1 | c.357G>A p.Q119= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV100056124; called by muse, mutect2, varscan2
- FZD5 | c.813C>T p.I271= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99776182; called by muse, mutect2, varscan2
- GRK5 | c.714C>T p.L238= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs760228524, COSV100962803; called by muse, mutect2, varscan2
- IGSF1 | c.2598C>T p.L866= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs767132682, COSV63836874; called by muse, mutect2, varscan2
- LRP1 | c.1119G>A p.T373= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1406975254, COSV54518912; called by muse, mutect2, varscan2
- MACF1 | c.19434G>A p.Q6478= (on ENST00000372915; = p.Q4523= on NM_012090.5) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99240953; called by muse, mutect2, varscan2
- MAST4 | c.7551G>A p.K2517= (on ENST00000403625 / NM_001164664.2; = p.K2328= on NM_015183.3) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99842700; called by muse, mutect2
- NR0B2 | c.435G>A p.A145= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs148569409; called by muse, mutect2, varscan2
- PI4KA | c.5262C>T p.G1754= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs752259850, COSV99744153; called by muse, mutect2, varscan2
- SLC5A9 | c.138C>T p.V46= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99361306, COSV99361373; called by muse, mutect2, varscan2
- SYCP2L | c.1542C>G p.T514= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99304611; called by muse, mutect2, varscan2
- TMTC4 | c.420G>A p.R140= (on ENST00000376234 / NM_001350577.2; = p.R159= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100168423; called by muse, mutect2, varscan2
- UNC79 | c.2550G>A p.Q850= (on ENST00000393151 / NM_001346218.2; = p.Q673= on NM_020818.5) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV56375409; called by muse, mutect2
- USH2A | c.4005T>C p.Y1335= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100228467; called by muse, mutect2, varscan2
- ZFYVE26 | c.2385G>A p.L795= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100720040; called by muse, mutect2, varscan2
- ZNF536 | c.1893C>T p.T631= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs201261663, COSV62825350; called by muse, mutect2, varscan2
- ZNF638 | c.5466A>G p.E1822= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100037951; called by muse, mutect2, varscan2
- C7orf66 | n.379T>G | RNA (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
